Somatic mutation profile of tumor specimen TCGA-E8-A417-01A (aliquot TCGA-E8-A417-01A-21D-A23M-08) from TCGA case TCGA-E8-A417, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 38.4 years (14,019 days).
Specimen TCGA-E8-A417-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bba220a9-c98b-4b12-88d5-8a13b13a6ef8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A417-10A (Blood Derived Normal), aliquot TCGA-E8-A417-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43354282-0fbb-4aab-91c3-63891e7d3b6d

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCB11 | c.2522G>T p.G841V | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV99791808; called by muse, mutect2
- ANO5 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100201651; called by muse, mutect2, varscan2
- ASAP1 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100727029; called by muse, varscan2
- ATP4A | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99382353; called by muse, mutect2
- CR1 | c.2756G>T p.R919L | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV100887484; called by muse, mutect2
- DHX29 | c.3286G>A p.D1096N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV99287123; called by muse, mutect2
- DRP2 | c.2220T>A p.N740K | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV100871851; called by muse, mutect2
- EEA1 | c.3067A>G p.K1023E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100467350; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs146338541; called by muse, mutect2, varscan2
- FRMD5 | c.1029-1G>C p.X343_splice | Splice Site (SNP) | VAF 13/94 reads (14%) | catalogued as COSV101296362; called by muse, mutect2
- FUT1 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 36/373 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV100038072; called by muse, mutect2, varscan2
- GAL3ST2 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV51951850; called by muse, mutect2
- ING1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV100312050; called by muse, mutect2
- MEI1 | c.1982A>T p.H661L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as COSV100299769; called by muse, mutect2, varscan2
- MKI67 | c.3311G>C p.G1104A | Missense Mutation (SNP) | VAF 38/321 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100896369; called by muse, mutect2, varscan2
- PDZD2 | c.2039C>G p.P680R | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56866614, COSV99224378; called by muse, mutect2, varscan2
- RB1CC1 | c.1727A>G p.D576G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1250909590, COSV99209902; called by muse, mutect2, varscan2
- SCAI | c.900G>A p.M300I (on ENST00000336505 / NM_001144877.3; = p.M323I on NM_173690.5) | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.708); catalogued as COSV100332427; called by muse, mutect2, varscan2
- THSD7B | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 20/112 reads (18%) | catalogued as rs1205607295, COSV55675719, COSV99747403; called by muse, mutect2, varscan2
- TTN | c.42289G>C p.V14097L (on ENST00000591111; = p.V6673L on NM_003319.4) | Missense Mutation (SNP) | VAF 15/211 reads (7%) | PolyPhen probably damaging (0.99); catalogued as COSV100602496, COSV59897366; called by muse, mutect2
- WDR72 | c.3228T>A p.C1076* | Nonsense Mutation (SNP) | VAF 66/302 reads (22%) | catalogued as COSV100854321; called by muse, mutect2, varscan2
- ABCA8 | c.723T>G p.S241= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99285291; called by mutect2, varscan2
- ADNP | c.789C>G p.P263= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as rs1168565109, COSV100823683; called by muse, mutect2
- KLHDC7A | c.153T>C p.N51= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1323073272, COSV101272748; called by muse, mutect2, varscan2
- ZFHX3 | c.5643C>T p.V1881= | Silent (SNP) | VAF 25/148 reads (17%) | catalogued as rs1188328440, COSV99196306; called by muse, mutect2, varscan2
